Somatic mutation profile of tumor specimen TCGA-HC-8262-01A (aliquot TCGA-HC-8262-01A-11D-2260-08) from TCGA case TCGA-HC-8262, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.3 years (20,946 days).
Specimen TCGA-HC-8262-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4195bca0-4be0-47f6-a82b-b0ec6d891072.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8262-10A (Blood Derived Normal), aliquot TCGA-HC-8262-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c664c8a3-b2e7-4dca-b320-c71cf2bd1bb7

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 23, Silent 8, Nonsense Mutation 2, Splice Region 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- ACTR3 | c.1183C>G p.H395D | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV54301262; called by muse, varscan2
- ATP13A3 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55464930; called by muse, mutect2, varscan2
- BEND3 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1554231572, COSV64681112; called by muse, mutect2, varscan2
- BNC1 | c.1957G>C p.G653R | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.422); catalogued as COSV61757612; called by muse, mutect2, varscan2
- CASZ1 | c.3130A>C p.T1044P | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59736069; called by muse, mutect2, varscan2
- COG7 | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56150452; called by muse, mutect2, varscan2
- COL27A1 | c.5365C>T p.R1789W | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1207484311, COSV61921530; called by muse, mutect2, varscan2
- DDX31 | c.1755G>T p.T585= | Splice Region (SNP) | VAF 6/36 reads (17%) | catalogued as COSV60134670, COSV60136211; called by muse, mutect2, varscan2
- HOXB3 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV61144708; called by muse, mutect2
- ITLN1 | c.187G>A p.G63S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.652); catalogued as COSV58275296; called by muse, mutect2, varscan2
- KIRREL1 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs924961577, COSV63286682, COSV63287434; called by muse, mutect2, varscan2
- MDM4 | c.786A>C p.Q262H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV65795724; called by muse, mutect2, varscan2
- MFAP5 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768885285, COSV63945029; called by muse, mutect2, varscan2
- MTUS1 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 9/144 reads (6%) | catalogued as COSV50559366; called by muse, mutect2
- PARP14 | c.5359T>G p.Y1787D | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.907); catalogued as COSV71734753; called by muse, mutect2, varscan2
- PCDH18 | c.2978A>T p.D993V | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV61268751; called by muse, mutect2, varscan2
- PCLO | c.10219G>A p.E3407K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as rs1282303356, COSV61621336; called by muse, mutect2, varscan2
- PHF23 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV50034751, COSV50036163; called by muse, mutect2, varscan2
- PRDM16 | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV54591758; called by muse, mutect2, varscan2
- SPANXC | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.993); catalogued as rs1415319273, COSV100748644, COSV62841725; called by muse, mutect2
- TMIE | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746409545, COSV58405810; called by muse, mutect2, varscan2
- TRIM9 | c.927T>G p.S309R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.418); catalogued as COSV53617824; called by muse, mutect2, varscan2
- TUBB6 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.625); catalogued as rs1350346094, COSV52314701; called by muse, mutect2, varscan2
- USH2A | c.10145T>A p.V3382D | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56375270; called by muse, mutect2, varscan2
- ZZEF1 | c.3187G>T p.E1063* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV67557719; called by muse, mutect2, varscan2
- FOXA1 | c.1414_*35del | Nonstop Mutation (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- MMP19 | c.1058_1060+1del p.X353_splice | Splice Site (DEL) | VAF 15/79 reads (19%) | called by mutect2, pindel, varscan2
- ANKH | c.1401G>A p.G467= | Silent (SNP) | VAF 48/189 reads (25%) | catalogued as COSV52481347; called by muse, mutect2, varscan2
- CRYBB2 | c.600C>T p.A200= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV68005509; called by muse, mutect2, varscan2
- DCHS1 | c.4953G>A p.Q1651= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV55036109; called by muse, mutect2, varscan2
- ERCC3 | c.411C>T p.T137= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs774188273, COSV53427278; called by muse, mutect2, varscan2
- KCTD14 | c.84G>T p.R28= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV62001503; called by muse, mutect2
- OR5M8 | c.84G>A p.T28= | Silent (SNP) | VAF 40/150 reads (27%) | catalogued as rs775937540, COSV59116922; called by muse, mutect2, varscan2
- RNF144A | c.384G>A p.Q128= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV57982652; called by muse, mutect2, varscan2
- ZNF236 | c.1083C>A p.L361= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV53489009; called by muse, mutect2, varscan2
